Somatic mutation profile of tumor specimen TARGET-30-PARZIP-01A (aliquot TARGET-30-PARZIP-01A-01D) from TARGET case TARGET-30-PARZIP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.2 years (2,273 days).
Specimen TARGET-30-PARZIP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87a735ec-7074-43fd-a698-1e8c425dac58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARZIP-10A (Blood Derived Normal), aliquot TARGET-30-PARZIP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454e5227-6343-4186-9605-63dc99b89c85

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3521T>G p.F1174C | Missense Mutation (SNP) | VAF 50/120 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519697, COSV66558767, COSV66560921; ClinVar: pathogenic; called by muse, varscan2
- BRD8 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs771114782, COSV54723871; called by mutect2, varscan2
- C1QTNF7 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1432634391, COSV54851174; called by muse, varscan2
- FGD2 | c.1351del p.R451Gfs*11 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV99235917; called by pindel, varscan2
- GAPDH | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV57520634; called by muse, mutect2, varscan2
- NFASC | c.1168G>A p.G390R (on ENST00000339876 / NM_001378329.1; = p.G401R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs764521110, COSV58361085; called by muse, varscan2
- PPEF2 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV54424995; called by muse, mutect2, varscan2
- SERPINA5 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1297836263, COSV100291432, COSV61573731; called by muse, varscan2
- SLITRK1 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV65675264; called by muse, mutect2
- TNC | c.4204G>T p.V1402L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as COSV60781904; called by muse, varscan2
- ADCY9 | c.3655A>G p.M1219V | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MKNK1 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by mutect2, varscan2
- NPRL3 | c.1078G>T p.D360Y (on ENST00000611875 / NM_001077350.3; = p.D335Y on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by mutect2, varscan2
- PAXBP1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by mutect2, varscan2
- SLC15A3 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by mutect2, varscan2
- AMOT | c.2538C>T p.P846= (on ENST00000371959 / NM_001113490.1; = p.P437= on NM_133265.3) | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- B4GALNT3 | c.606C>A p.V202= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV56758038; called by mutect2, varscan2
- LRIT1 | c.1593G>T p.V531= | Silent (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- OR4A47 | c.555G>T p.L185= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as COSV71444872; called by mutect2, varscan2
- TIMM23 | c.159C>A p.L53= | Silent (SNP) | VAF 41/735 reads (6%) | called by muse, mutect2
- HDAC7 | c.-59C>G | 5'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, varscan2
- TPM4 | c.*424G>A | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as COSV56288246; called by muse, varscan2
- ZNF304 | c.161-659C>A | Intron (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
